Surgical pathology report (de-identified scan), TCGA case TCGA-56-A62T, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-A62T-01A (Primary Tumor).

[page 1 of 5]
Patient:

Referring Physician:

DOB: Age: Gender: M

Ref#: Hosp#: Provider Group :

Date of Service: Date Received: Case #: Date Reported:

Items were attached to this order:
Items were attached to this order:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

- A. B.
D. E. LUNG, LEFT UPPER LOBE, ADDITIONAL BRONCHIAL MARGIN, HILAR AND SUBCARINAL (N10L and N7), LYMPH NODES, LOBECTOMY, MARGIN EXCISION AND LYMPH NODE EXCISION:

- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED.
- Size 5.5 cm.
- Tumor invades through visceral pleura.
- MARGINS:
- Bronchial and vascular margin negative.
- Pleural surface POSITIVE.
- TWO BENIGN LYMPH NODES (0/2).

*ICD-O-3
Carcinoma, squamous cell
Site Lung, upper lobe
8070/3
34.1
5/10/13*

- C. PULMONARY LIGAMENT, N9L, EXCISION:
- TYPICAL CARCINOID, 0.9 cm.

PATHOLOGIC TUMOR STAGING DESCRIPTORS:

Histologic type and grade: Squamous cell carcinoma, Grade 2, moderately differentiated.

Primary tumor: pT2b.

Regional lymph nodes: pN0.

Distant metastasis: Not applicable.

Pathologic stage: IIB.

Margin status: R1, POSITIVE pleural surface; bronchial margin negative.

Lymphovascular invasion: Not identified.

Perineural invasion: Not identified.

COMMENT: In one section of the outer pleural surface, there is dense fibrosis extensively involved by squamous cell carcinoma. The tumor involves the inked

Case #

Page 1

Printed:

This report continues (FINAL)

[page 2 of 5]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

surface. It is difficult to determine the plane of the actual parietal pleura in regards to this focus of tumor. Therefore this tumor is classified as a T2b and the stage otherwise remains the same at IIB.

was informed of these results on

Lung Tumor Staging Information

AJCC Cancer Staging Handbook, 7th Ed., and CAP Protocol (revised 1/1/13)

Case #

Printed:

Page 2

This report continues (FINAL)

MR No.

Patient N

[page 3 of 5]
Patient:

Case #:

Specimen:	Lung, upper lobe, hilar and subcarinal lymph node.
Procedure:	Lobectomy and lymph node excisions.
Specimen integrity:	Intact.
Specimen laterality:	Left.
Tumor focality:	Unifocal.
Histologic type:	Squamous cell carcinoma.
Histologic grade:	Grade 2, moderately differentiated.
Visceral pleural invasion:	Positive.
Tumor extension:	Through visceral pleura with involvement of dense fibrous tissue

MARGINS:

Bronchial margin:	Negative.
Vascular margin:	Negative
Parenchymal margin:	Negative
Pleura margin:	POSITIVE.
Chest wall margin:	Not applicable.

Treatment effect:

Not applicable.

Lymphovascular invasion:

Not identified.

LYMPH NODES:

Two benign lymph nodes (0/2).

PATHOLOGIC STAGE:

Primary tumor:	pT2b.
Regional lymph nodes:	pN0.
Distant metastasis:	Not applicable
Pathologic stage:	IIB.

Signed by

Case #

Page 3

Printed:

This report continues. (FINAL)

[page 4 of 5]
Patient:

Case #

FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Lung; Left upper lobe-check bronchial margins
- B. Lung; New bronchial margin
- C. Lymph node; N9L
- D. Lymph node; N10L
- E. Lymph node; N7

Clinical History/Operative Dx:

Lung cancer.

Intraoperative Diagnosis:

- A. Left lung resection (FSA1): Focus of squamous epithelium, cannot exclude tumor at margin.
- B. New bronchial margin (FSB1): No tumor identified.

The intraoperative interpretation(s) was/were performed and rendered at

Gross Description:

A. The specimen is labeled left upper lobe and is received without fixative. It consists of a lobe of lung measuring 11 x 9.3 x 6.0 cm and weighing 170 grams. The pleural surface is violet to pale red with numerous string adhesions along the anterior surface and toward the basilar portion. The lateral apical portion of the lobe has a mottled yellow-tan to pink to reddish violet appearance with thickening of the pleura over an area measuring 7.5 x 5 cm. The bronchial margin is identified and is removed as a thin shave for en face frozen section. On dissection there is an apical tumor mass which is composed of tan to pale yellow to pale red tissue and overall measures 5.5 x 5.2 x 4 cm. This tumor is centrally cavitory containing blood clot. This lesion is grossly 0.5 cm from the bronchial margin and abuts the pleural surface in numerous areas. The inferior edge of the lung has a ratty irregular appearance. An intralobar fissure is not appreciated grossly. This tumor mass is 2 cm from the closest inferior edge. The remaining lung has a wet soggy consolidated appearance. Representative sections are submitted. Section summary: A1) bronchial margin from frozen section, A2) vascular margins, A3) section of main bronchus with closest approach of tumor, A4) tumor and pleural surface, A5-A7) sections of tumor, A8-A9) uninvolved lung.

B. The specimen is labeled new bronchial margin and is received without fixative. It consists of a 1.4 x 1.2 x 0.7 cm portion of bronchus. A suture is present marking the new margin. Staples are present at both ends. The staples are trimmed free and the remaining tissue is submitted for frozen section as BFS, with the side closest to the new margin en face. The tissue remaining from frozen section is submitted for permanent section in cassette B1.

C. The specimen is labeled N9L and is received in formalin. It consists of a 0.7 x 0.4 x 0.3 cm fragment of pale yellow to pink-tan soft tissue. It is bisected longitudinally and submitted in cassette C1.

Case #

Printed:

Page 4.

This report continues... (FINAL)

MR No.

Acct No.

Patient Name

[page 5 of 5]
Patient:

Case #

FINAL SURGICAL PATHOLOGY REPORT

D. The specimen is labeled N10L and is received in formalin. It consists of a 1.9 x 0.7 x 0.6 cm fragment of gray-tan anthracotic tissue. It is serially sectioned and entirely submitted in cassette D1.

E. The specimen is labeled N7 and is received in formalin. It consists of a 0.8 x 0.4 x 0.3 cm fragment of pale yellow to anthracotic tissue. It is bisected longitudinally and submitted in cassette E1.

Microscopic Description:

A. Sections of the lobectomy show an invasive squamous cell carcinoma predominantly forming angulated and irregular nests with enlarged nuclei and occasional prominent nucleoli. There is mild keratin formation with intercellular bridges and punctate necrosis. The tumor is away from the bronchial and vascular margin but does invade through the visceral pleura where there is dense fibrosis. Tumor is at the inked outer margin. No diagnostic lymphovascular or perineural invasion is identified. The uninvolved lung has minimal changes. The rounded focus at the bronchial margin on the frozen section slide is a rounded aggregate of degenerate hyaline cartilage that has some squamoid features.

B. Sections of the additional bronchial margin show benign bronchus and surrounding lung tissue uninvolved by malignancy.

C. Sections of the pulmonary ligament N9L specimen show a distorted fragment of lung tissue with a nested well differentiated neoplastic process at one edge measuring 0.9 cm. The cells are uniformly small with oval nuclei and even lightly speckled chromatin. No necrosis or mitotic activity is present. The lesion is at the distorted edge of the tissue. Immunohistochemistry shows the lesion is positive for chromogranin and synaptophysin. The tumor is negative for pancytokeratin.

D. Sections of the hilar N10L lymph node show a single benign lymph node (0/1) with focal fibrosis. No malignancy is identified.

E. Sections of the subcarinal N7 lymph node show a single benign lymph node (0/1). No malignancy is identified.

Page 5

Case #:

Printed:

END OF REPORT (FINAL)

Source: NCI Genomic Data Commons file 7b08b54f-8c6f-455a-88d0-e1d2baff2c9c (TCGA-56-A62T.8A436D40-6B36-4A34-B589-BFCCCE228F5C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).